Gene-level copy-number profile of tumor specimen TCGA-BP-4799-01A from TCGA case TCGA-BP-4799, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 70.8 years (25,842 days).
Specimen TCGA-BP-4799-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.b8d3f353-e8e5-4a95-8da5-3d76f7fc6ad3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-4799-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17da2a14-20a3-4120-809d-d32ef45b14fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,552; copy number 3: 443; copy number 4: 29,520; copy number 5: 2,217; copy number 6: 16,624; copy number 7: 475; copy number 8: 3,451; copy number 9: 4; copy number 10: 1,183; copy number 11: 351.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BP-4799-01): tumor purity 0.33, ploidy 2.53, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,538 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 10–11 (broad region; genes not listed).
- chr12:20,368,537–20,688,583, 1 gene, copy number 9 (within-gene range 2–9): PDE3A.
- chr12:20,551,590–20,753,386, 2 genes, copy number 9: AC112777.1, SLCO1C1.
- chr12:20,845,065–20,845,260, 1 gene, copy number 9: AC011604.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
